Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A4M9, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A4M9-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Thyroid, right lobe and isthmus, partial thyroidectomy
(specimen revised, see Amendment Comment below)

Tumor growth pattern: Papillary thyroid carcinoma, follicular and solid types

Tumor focality & location: Two foci

ICD-O-3

cQCF: carcinoma, papillary, thyroid, 8260/3

Tumor size: 3.0 cm, 0.3 cm

Path: carcinoma, papillary and follicular 8340/3

Site: thyroid, NOS C73.9

Tumor capsule: Not encapsulated

W
10/2/12

Extent of invasion:

Capsular Invasion: n/a

Vascular invasion: Present (A6, 12, 18)

Extra-thyroidal extension invasion: Not identified

Surgical margins: Focally positive anterior margin (A9, 10);
<1mm to posterior margin (A18)

Status of thyroid gland away from tumor: Nodular hyperplasia

Lymph nodes: None received with this specimen

AJCC Pathologic Stage: pT2 pNx pMx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Comment:

Amendment Comment:

Following case finalization, it was brought to our attention that this distorted specimen is only the right lobe and isthmus, rather than the entire thyroid.

The dominant focus of carcinoma corresponds to the large right lobe nodule, and is present in blocks A1-A18. A separate small focus is present in grossly normal gland in block A20. The diagnosis and margin status are unchanged. The specimen received is revised from total thyroidectomy to R lobe/isthmus, as above.

[page 2 of 3]
Clinical History:

-year-old male with right thyroid nodule interpreted as atypia of undetermined significance on FNA.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right isthmus and thyroid".

Specimen fixation: Formalin

Type of specimen: Total thyroidectomy

Size and weight of specimen: 30 grams, right lobe nodule (3.2 x 2.8 x 2.3 cm), remainder of left lobe and isthmus roughly (3.2 x 2.7 x 1.3 cm)

Orientation: Inking: anterior/blue, posterior/black, isthmus/yellow

Tumor location: Right lobe

Focality: Unifocal

Dominant tumor: Right

Tumor description: Firm gray/white well-circumscribed, smooth with focal hemorrhage

Tumor size: 3.0 x 2.5 x 2.0 cm

Confinement / non-confinement: Confined

Distance of tumor to capsule/inked surgical margins: Grossly abuts the anterior and posterior capsule and isthmus, but with no extension into the isthmus.

Appearance of thyroid gland away from tumor: The uninvolved right thyroid parenchyma and all of the left thyroid parenchyma is soft, red/brown with normal architecture.

Parathyroids: Not identified

Lymph nodes: N/A

Tissue submitted for special investigations: Tumor given to tumor procurement foundation.

[page 3 of 3]
Digital photograph taken: No

Block Summary:

A1-A18 - Right lobe nodule from inferior to superior (nodule submitted entirely)

A19-A22 - Representative sections from remainder of grossly normal right lobe and isthmus)

Diagnostic Discrepancy		X
Histologic Discrepancy		X
Pathologic Discrepancy History		X
Discrepancy Primary Noted		X

WML

Source: NCI Genomic Data Commons file 62a177fd-ebb5-473e-a854-06c8e49d11dd (TCGA-DE-A4M9.B3CF4E37-3430-4092-BC7D-5E5534DCE531.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).